Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A81E, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A81E-01A (Primary Tumor).

Unique Patient Identifier:

Short descriptive translation of the pathology review reported by the

Pathoanatomical review

Date:

Date report:

Material: mediastinal paraganglioma

This is a reddish to light-colored 42 g specimen measuring 5x4x3 cm. The tumor is reddish to light tan, and partly rose.

Histologically, the tumor is composed of Zellballen with medium sized cells with enlarged nuclei with chromatin and well distinguishable nucleoli. Single pleomorph nuclei are visible. One focal sclerosis with necrosis is present. However, no extensive necrosis and no enhanced number in mitosis are found. No vessel invasion.

Final diagnosis: extra-adrenal paraganglioma

Translated by:

ICD-O-3
Paraganglioma, extra-adrenal, malignant 8693/3
Site: Mediastinum NOS C38.3
QID 10/17/13

Case Is (Check)		

10/18/13

Source: NCI Genomic Data Commons file 58f08d37-fb1b-43a1-a25d-03cb23e1b993 (TCGA-WB-A81E.F3F9A6A0-4058-40A8-AB6F-BD36EFB48257.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).